Somatic mutation profile of tumor specimen C3N-02028-03 (aliquot CPT0133600006) from CPTAC case C3N-02028, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.3 years (24,954 days).
Specimen C3N-02028-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c0b9ec-d934-42f2-9dad-06443763e4ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02028-71 (Blood Derived Normal), aliquot CPT0133700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19dc6b27-ca84-426d-937f-efda6d99049a

The open-access MAF lists 1,079 somatic variants for this specimen: 703 protein-altering or splice-affecting, 235 silent, 141 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 481, Silent 235, Frame Shift Del 135, Intron 72, Frame Shift Ins 35, 3'UTR 22, Nonsense Mutation 21, RNA 15, 5'UTR 15, Splice Site 13, Splice Region 12, 3'Flank 10.

Variants (750 of 1,079; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 52/288 reads (18%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- COL1A1 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs67828806, CM051413, CM960319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 63/421 reads (15%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 66/406 reads (16%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 55/409 reads (13%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 33/196 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 40/213 reads (19%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 18/174 reads (10%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 23/151 reads (15%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PURA | c.159dup p.L54Afs*147 | Frame Shift Ins (INS) | VAF 28/155 reads (18%) | catalogued as rs1554129040; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARS1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 71/480 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434447541; called by muse, mutect2, varscan2
- ABCB8 | c.1616G>A p.R539H (on ENST00000297504 / NM_001282291.2; = p.R522H on NM_007188.5) | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1233230045; called by muse, mutect2
- ABCC2 | c.3641T>C p.V1214A | Missense Mutation (SNP) | VAF 91/508 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs200286512; called by muse, mutect2, varscan2
- AC005863.1 | n.334+1G>A | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as rs752666164; called by muse, mutect2, varscan2
- ACACB | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | catalogued as rs142989070; called by muse, mutect2, varscan2
- ACSM2A | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54587226; called by muse, mutect2, varscan2
- ACTR1A | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as rs767685674, COSV100883731, COSV64023594; called by muse, mutect2, varscan2
- ADAM15 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.482); catalogued as rs146469436; called by muse, mutect2, varscan2
- AGBL2 | c.2482del p.L828Wfs*8 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs1310675921; called by mutect2, pindel, varscan2
- AGRN | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 77/449 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as rs1256837701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHR | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); catalogued as rs770650129, COSV54124754; called by muse, mutect2, varscan2
- ANAPC7 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs768592404, COSV71443990; called by muse, mutect2, varscan2
- ANKRD35 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1553738943, COSV62911223; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 25/160 reads (16%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- ARHGAP25 | c.1265G>A p.S422N (on ENST00000409202 / NM_001007231.3; = p.S414N on NM_014882.3) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs761008026; called by muse, mutect2
- ARHGAP4 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs368238109; called by muse, mutect2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 38/231 reads (16%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ATG4B | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1326302400; called by muse, mutect2
- ATP8A2 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.434); catalogued as rs199725711, COSV99681789; called by muse, mutect2, varscan2
- ATXN7L3 | c.605G>A p.R202H (on ENST00000389384 / NM_001382309.1; = p.R209H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs751741019, COSV60228645; called by muse, mutect2, varscan2
- BCKDK | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.409); catalogued as rs374568685; called by muse, mutect2, varscan2
- BCOR | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60717189; called by muse, mutect2, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as rs749168305; called by mutect2, varscan2
- BFSP2 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56589533; called by muse, mutect2
- BIRC2 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99926914; called by muse, mutect2, varscan2
- BIRC6 | c.6783A>G p.I2261M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs781753954; called by muse, mutect2, varscan2
- BLM | c.3922G>A p.G1308R | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768010078, COSV61921721, COSV61927945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPTF | c.5567del p.K1856Sfs*45 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as COSV58837593, COSV58840953; called by mutect2, varscan2
- BRAT1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs139472984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD8 | c.1886del p.N629Mfs*9 (on ENST00000636805 / NM_001376131.1; = p.N116Mfs*9 on NM_015237.4) | Frame Shift Del (DEL) | VAF 9/102 reads (9%) | catalogued as rs774107642; called by mutect2, pindel
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | catalogued as rs757227190; called by mutect2, varscan2
- C19orf44 | c.1352G>A p.S451N | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs1318421278; called by muse, mutect2, varscan2
- C1orf167 | c.3188C>T p.T1063I | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs1173966782, COSV57173867; called by muse, mutect2
- C1orf68 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1217046707; called by muse, mutect2
- C20orf194 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs780158228; called by muse, mutect2
- CACNA1C | c.6191G>A p.G2064D (on ENST00000399634 / NM_001167625.1; = p.G1993D on NM_000719.7) | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1004378365, COSV59744158; called by muse, mutect2, varscan2
- CACNA1G | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV61727933; called by muse, mutect2, varscan2
- CAMK2G | c.1135A>G p.K379E (on ENST00000423381 / NM_001367518.1; = p.K345E on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/452 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as rs1308478175; called by muse, mutect2, varscan2
- CAMSAP2 | c.7del p.D3? | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as COSV52670732; called by mutect2, pindel
- CAPN15 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774748919, COSV54840568; called by muse, mutect2, varscan2
- CCDC105 | c.876G>A p.A292= | Splice Region (SNP) | VAF 20/108 reads (19%) | catalogued as rs748358227, COSV52963196; called by muse, mutect2
- CCR3 | c.983T>A p.I328N | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs1237177318; called by muse, mutect2, varscan2
- CDH24 | c.771dup p.K258Qfs*48 | Frame Shift Ins (INS) | VAF 23/121 reads (19%) | catalogued as rs753422808; called by mutect2, varscan2
- CDK11B | c.1963G>T p.G655W | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189900905; called by muse, mutect2, varscan2
- CDNF | c.466del p.E156Rfs*13 | Frame Shift Del (DEL) | VAF 38/395 reads (10%) | catalogued as COSV101012365; called by mutect2, pindel
- CEP170 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs754809055; called by muse, mutect2, varscan2
- CFAP44 | c.3423del p.E1142Nfs*35 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs947129972; called by pindel, varscan2
- CFAP61 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.708); catalogued as rs1477276055, COSV55646623; called by muse, mutect2, varscan2
- CLCN2 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs868631476; called by muse, mutect2
- CLCNKB | c.1620C>T p.I540= | Splice Region (SNP) | VAF 86/543 reads (16%) | catalogued as rs767549795, COSV65161754; called by muse, mutect2, varscan2
- CNN2 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); catalogued as rs756697104, COSV99566700; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN3 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99725678; called by muse, mutect2, varscan2
- COL11A1 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs758303420; called by muse, mutect2, varscan2
- COL18A1 | c.2143G>A p.E715K (on ENST00000359759 / NM_130444.3; = p.E480K on NM_030582.4) | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs752384135; called by muse, mutect2, varscan2
- CRYAB | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs930811941, COSV57052860; called by muse, mutect2
- CUX1 | c.3547G>A p.V1183I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs201799537, COSV99470537; called by muse, mutect2, varscan2
- CUX1 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52909305; called by muse, mutect2, varscan2
- CYP2A7 | c.1151dup p.L385Pfs*3 | Frame Shift Ins (INS) | VAF 22/145 reads (15%) | catalogued as rs774434674; called by mutect2, pindel
- DACH1 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1347734862; called by muse, mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCAF8L2 | c.1478A>G p.H493R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211802180; called by muse, mutect2, varscan2
- DCLK1 | c.252del p.F84Lfs*8 | Frame Shift Del (DEL) | VAF 53/307 reads (17%) | catalogued as COSV99713743; called by mutect2, pindel, varscan2
- DES | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 24/632 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as COSV64660265; called by muse, mutect2
- DIDO1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 47/338 reads (14%) | catalogued as COSV56620631; called by muse, mutect2, varscan2
- DIXDC1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 42/279 reads (15%) | catalogued as rs201776848; called by muse, mutect2, varscan2
- DLG5 | c.4580C>T p.A1527V | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV64946990; called by muse, mutect2, varscan2
- DLL3 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 85/520 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs757298214; called by muse, mutect2, varscan2
- DMD | c.4181C>A p.A1394E | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV63740909; called by muse, mutect2, varscan2
- DOCK6 | c.5615G>A p.R1872H | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756208935; called by muse, mutect2, varscan2
- DOT1L | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774144803, CM155055; called by muse, mutect2
- EGR4 | c.79del p.E27Sfs*127 | Frame Shift Del (DEL) | VAF 45/234 reads (19%) | catalogued as rs1254850903; called by mutect2, pindel, varscan2
- ELANE | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs201882944; called by muse, varscan2
- EMC9 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 103/567 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.948); catalogued as COSV99246490; called by muse, mutect2, varscan2
- EPHB2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982617664; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- ERC1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs771123374; called by muse, mutect2, varscan2
- F8 | c.6724-2A>G p.X2242_splice | Splice Site (SNP) | VAF 30/204 reads (15%) | catalogued as CS153706; called by muse, mutect2, varscan2
- FAM20C | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1297906375; called by muse, mutect2, varscan2
- FAM217B | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100674611; called by muse, mutect2
- FAM83H | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 178/944 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs782223642; called by muse, mutect2
- FAXC | c.13dup p.V5Gfs*85 | Frame Shift Ins (INS) | VAF 25/144 reads (17%) | catalogued as rs773334184; called by mutect2, pindel, varscan2
- FGD1 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as rs769308984, COSV64308541; called by muse, mutect2, varscan2
- FIGNL2 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.797); catalogued as COSV73729254; called by muse, mutect2, varscan2
- FLG | c.10890C>G p.H3630Q | Missense Mutation (SNP) | VAF 90/877 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs781364566; called by muse, mutect2, varscan2
- FNDC1 | c.3071C>T p.A1024V | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1008907074; called by muse, mutect2
- FNDC4 | c.22dup p.S8Ffs*31 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | catalogued as COSV53020608, COSV53020744; called by mutect2, pindel, varscan2
- FOXRED1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 84/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377464580; called by muse, mutect2, varscan2
- FRMPD1 | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.765); catalogued as rs778737300; called by muse, mutect2, varscan2
- FSIP2 | c.1139del p.N380Tfs*16 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1559014390; called by mutect2, varscan2
- FURIN | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs774139084; called by muse, mutect2
- FUT4 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs767600530, COSV100708134; called by muse, mutect2, varscan2
- FZD1 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 25/451 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1347489084, COSV55309247; called by muse, mutect2
- GABRA6 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99193995; called by muse, mutect2, varscan2
- GDF10 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1555207558; called by muse, mutect2, varscan2
- GFRA2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195206492, COSV60780567; called by muse, mutect2, varscan2
- GPR108 | c.723G>A p.T241= | Splice Region (SNP) | VAF 25/151 reads (17%) | catalogued as rs199564830; called by muse, mutect2, varscan2
- GPR176 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV100137310; called by muse, varscan2
- GPR179 | c.3809C>T p.T1270M (on ENST00000621958; = p.T1269M on NM_001004334.4) | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754266923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR50 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1462706023, COSV54439973; called by muse, mutect2, varscan2
- GRAMD1A | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs749587215, COSV58766006, COSV58769025; called by muse, mutect2, varscan2
- GRIN2A | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 12/369 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM138215; called by muse, mutect2
- GRIN2C | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1204301028; called by muse, mutect2, varscan2
- GRM2 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371451244, COSV56584801; called by muse, mutect2, varscan2
- H6PD | c.1976A>G p.Q659R | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs759694369; called by muse, mutect2, varscan2
- HOOK2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs139576838; called by muse, mutect2, varscan2
- HS6ST1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 74/586 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278055169; called by muse, varscan2
- HSPA1L | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 15/545 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs745365008, COSV100989365; called by muse, mutect2
- HYAL4 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418335449; called by muse, mutect2, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as COSV63641012; called by mutect2, pindel, varscan2
- IL1RAPL1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs751673587, COSV56245277; called by muse, mutect2, varscan2
- IL23R | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1468346338; called by muse, mutect2
- INPPL1 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1380449984, COSV53355415; called by muse, mutect2, varscan2
- ITGA5 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.111); catalogued as rs746124596, COSV99516742; called by muse, mutect2, varscan2
- KANK2 | c.1518C>T p.G506= (on ENST00000586659 / NM_001379562.1; = p.G514= on NM_015493.7 and 7 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as rs1235103955, COSV100763069; called by muse, mutect2, varscan2
- KCND2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310731566, COSV58576394; called by muse, mutect2, varscan2
- KCTD19 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs371354193; called by muse, mutect2, varscan2
- KCTD8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100759261; called by muse, mutect2, varscan2
- KHDRBS2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as rs372434154; called by muse, mutect2
- KHK | c.653+8G>A | Splice Region (SNP) | VAF 22/166 reads (13%) | catalogued as rs369037689; called by muse, mutect2, varscan2
- KIAA0753 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs766444004, COSV63819246; called by muse, mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs771825279; called by mutect2, varscan2
- KIF7 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs967769378; called by muse, mutect2, varscan2
- KIT | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55387589; called by muse, mutect2, varscan2
- KNDC1 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758782146, COSV100464491, COSV58833843; called by muse, mutect2, varscan2
- KRT6A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1481146150, COSV58106673; called by muse, mutect2
- KRT81 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100576993; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 85/487 reads (17%) | catalogued as rs1406609727; called by mutect2, varscan2
- LAMA2 | c.4811C>T p.A1604V | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.772); catalogued as rs748127741, COSV70343839; called by muse, mutect2, varscan2
- LGI3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs776385263, COSV60444213; called by muse, mutect2
- LRP2 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55570305; called by muse, mutect2, varscan2
- LRP5 | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53710672; called by muse, mutect2, varscan2
- LRRC24 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as rs866841814, COSV52879334; called by muse, mutect2, varscan2
- LRRC8C | c.2099del p.P700Lfs*35 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | catalogued as rs1557671997; called by mutect2, pindel, varscan2
- LRRN3 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV57824312; called by muse, mutect2, varscan2
- LYG1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs1277660668, COSV57915197; called by muse, mutect2, varscan2
- LYPD5 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs986597726; called by muse, mutect2, varscan2
- LZTS3 | c.1685C>T p.A562V (on ENST00000329152; = p.A516V on NM_001282533.2) | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1233825991, COSV99417698; called by muse, mutect2
- MAGEL2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.06); catalogued as rs963784720, COSV58568499; called by muse, mutect2, varscan2
- MAN1C1 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376670457; called by muse, mutect2, varscan2
- MAN2C1 | c.1461-2A>G p.X487_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as rs369736781; called by muse, mutect2, varscan2
- MAP3K4 | c.3095A>G p.Y1032C | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs1472613756; called by muse, mutect2
- MARCHF3 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 51/392 reads (13%) | catalogued as COSV58036805; called by muse, mutect2, varscan2
- MARF1 | c.4937A>G p.Q1646R | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs1369398313; called by muse, mutect2, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs767720617; called by mutect2, varscan2
- MCF2L | c.718A>G p.M240V (on ENST00000375608; = p.M208V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65050357; called by muse, mutect2
- MCOLN2 | c.1230G>A p.M410I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV52299189; called by muse, mutect2, varscan2
- MDGA1 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs779833010, COSV51796234; called by mutect2, varscan2
- MESP2 | c.718del p.V240Sfs*241 | Frame Shift Del (DEL) | VAF 34/212 reads (16%) | catalogued as rs756232049; ClinVar: uncertain significance; called by mutect2, varscan2
- METTL24 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58823927; called by muse, mutect2, varscan2
- MFSD6L | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as COSV61002178; called by muse, mutect2, varscan2
- MLNR | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs1372559333, COSV54534698; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MORC2 | c.395G>A p.R132H (on ENST00000397641 / NM_001303256.3; = p.R70H on NM_014941.3) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99310668; called by muse, mutect2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MTMR10 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 19/361 reads (5%) | catalogued as rs1477482617; called by muse, mutect2
- MUC17 | c.10787C>A p.P3596H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1038384282; called by muse, mutect2, varscan2
- MUC3A | c.940del p.L314Yfs*5 | Frame Shift Del (DEL) | VAF 38/191 reads (20%) | catalogued as COSV60222562; called by mutect2, pindel, varscan2
- MYBBP1A | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs748400049, COSV54598415; called by muse, mutect2, varscan2
- MYH14 | c.4822C>T p.R1608W | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1249048707, COSV51833242; called by muse, mutect2, varscan2
- MYH7 | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62516404; called by muse, mutect2, varscan2
- MYORG | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); catalogued as rs868589420, COSV52626897; called by muse, mutect2
- NCKAP5 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs752772984, COSV100489361; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel
- NDUFA6 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 30/229 reads (13%) | catalogued as rs969146834; called by muse, mutect2, varscan2
- NETO2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs767911742; called by muse, mutect2
- NIT1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); catalogued as rs757702515; called by muse, mutect2, varscan2
- NKTR | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs1039138786, COSV51774323; called by muse, mutect2, varscan2
- NLRX1 | c.1887del p.L630Ffs*10 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs749769992; called by mutect2, pindel, varscan2
- NOC4L | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201493263; called by muse, mutect2, varscan2
- NOL8 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766780387; called by muse, mutect2, varscan2
- NPSR1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV62204897; called by muse, mutect2
- NRROS | c.1358del p.P453Lfs*12 | Frame Shift Del (DEL) | VAF 34/255 reads (13%) | catalogued as rs1287233013; called by mutect2, pindel, varscan2
- NRXN1 | c.4016C>T p.P1339L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1293109274, COSV60506979, COSV60525112; called by muse, mutect2, varscan2
- NRXN2 | c.4790G>A p.R1597H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV55451157; called by muse, mutect2, varscan2
- NUP88 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759038421; called by muse, mutect2, varscan2
- OBSCN | c.4367C>T p.A1456V | Missense Mutation (SNP) | VAF 78/488 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs1431378910, COSV52790532; called by muse, mutect2, varscan2
- OGA | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs770327656; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OSBPL7 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757418024, COSV99136682; called by muse, mutect2, varscan2
- OXCT1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs200306864, COSV52167403; called by muse, mutect2, varscan2
- PADI1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969237; called by muse, mutect2, varscan2
- PAK6 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs764247717; called by muse, mutect2, varscan2
- PALLD | c.2936G>A p.R979H (on ENST00000505667 / NM_001166108.2; = p.R962H on NM_016081.4) | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296530962, COSV54979077; called by muse, mutect2, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 35/208 reads (17%) | catalogued as rs1564621823; called by mutect2, varscan2
- PAQR3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779349241; called by muse, mutect2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 29/200 reads (15%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 32/365 reads (9%) | catalogued as CM011452; called by mutect2, pindel
- PCDHA8 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as rs782268321; called by muse, mutect2, varscan2
- PCDHGA12 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1394486228; called by muse, varscan2
- PCDHGB4 | c.2107G>A p.V703M | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV53966571; called by muse, mutect2, varscan2
- PCED1B | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs112959993, COSV71395039; called by muse, mutect2, varscan2
- PCK2 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148751402; called by muse, mutect2, varscan2
- PCNX2 | c.6153G>T p.E2051D | Missense Mutation (SNP) | VAF 69/541 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV50836151; called by muse, mutect2, varscan2
- PDE8A | c.1036+4C>T | Splice Region (SNP) | VAF 24/122 reads (20%) | catalogued as rs370680030; called by muse, mutect2, varscan2
- PHF23 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs533278658, COSV50039892; called by muse, mutect2, varscan2
- PHF7 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as rs762575967, COSV56233875, COSV56242215; called by muse, mutect2, varscan2
- PIGG | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.265); catalogued as rs374780994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs574099162, COSV61872779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLEC | c.1660G>A p.A554T (on ENST00000322810 / NM_201380.4; = p.A444T on NM_000445.5) | Missense Mutation (SNP) | VAF 15/490 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781879136; ClinVar: uncertain significance; called by muse, mutect2
- PLXDC2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754065346, COSV65909610; called by muse, varscan2
- PNPLA7 | c.3522dup p.I1175Hfs*28 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | catalogued as rs761459630; called by mutect2, varscan2
- POGK | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV63311388; called by muse, mutect2
- POLR3A | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1319518839, COSV100965716; called by muse, mutect2, varscan2
- POTEF | c.2237dup p.M747Hfs*35 | Frame Shift Ins (INS) | VAF 84/789 reads (11%) | catalogued as rs760191584; called by mutect2, pindel, varscan2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1056475720, COSV52881818; called by mutect2, varscan2
- PRKD1 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1016932283; called by muse, mutect2, varscan2
- PRM3 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs368334860; called by muse, mutect2, varscan2
- PRSS57 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376572374; called by muse, mutect2, varscan2
- PSMA8 | c.495+2T>C p.X165_splice | Splice Site (SNP) | VAF 11/73 reads (15%) | catalogued as COSV57601460; called by muse, mutect2, varscan2
- PTHLH | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758972275, COSV52367099; called by muse, mutect2, varscan2
- PTPN5 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); catalogued as rs1288347887; called by muse, mutect2, varscan2
- PTPRC | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 97/576 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61421367; called by muse, mutect2, varscan2
- R3HDM4 | c.616del p.Q206Rfs*8 | Frame Shift Del (DEL) | VAF 21/164 reads (13%) | catalogued as rs771757743; called by mutect2, pindel, varscan2
- RAB3GAP2 | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749093248, COSV62786424; called by muse, mutect2, varscan2
- RABGAP1L | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs1248110639; called by muse, mutect2
- RAPGEF6 | c.1927C>T p.H643Y | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99725889; called by muse, mutect2, varscan2
- RAPGEF6 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs545717130; called by muse, mutect2
- RBBP4 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV100995628; called by muse, mutect2, varscan2
- RBM42 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777226810, COSV99387307; called by muse, mutect2
- RCBTB1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs150189495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RETN | c.-10C>T | Splice Region (SNP) | VAF 21/146 reads (14%) | catalogued as rs545198984, COSV55568768; called by muse, mutect2, varscan2
- RGS14 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1345826148; called by muse, mutect2, varscan2
- RGS14 | c.1056C>T p.A352= | Splice Region (SNP) | VAF 23/171 reads (13%) | catalogued as rs889480883; called by muse, mutect2, varscan2
- RIN2 | c.2720C>T p.A907V (on ENST00000255006 / NM_001242581.1; = p.A858V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373644035; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RMND5B | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100523352; called by muse, mutect2, varscan2
- RNF144B | c.382_385del p.T128Cfs*22 | Frame Shift Del (DEL) | VAF 53/456 reads (12%) | catalogued as rs754489571; called by mutect2, pindel, varscan2
- RPL28 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs772932918, COSV100689382; called by muse, mutect2, varscan2
- RPRD2 | c.3697A>G p.T1233A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs781152002; called by muse, mutect2, varscan2
- RSKR | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 19/139 reads (14%) | catalogued as COSV56382626; called by muse, mutect2, varscan2
- RSPH10B | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.368); catalogued as rs1348373791; called by muse, mutect2, varscan2
- RTN4RL1 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1432751867; called by muse, mutect2
- RUNX1T1 | c.1412C>T p.A471V (on ENST00000265814 / NM_001198628.1; = p.A444V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1462140811, COSV56138272; called by muse, mutect2, varscan2
- SALL3 | c.3791G>T p.R1264L | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as rs200493832, COSV73306440; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 74/503 reads (15%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD10 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV53878917; called by muse, mutect2, varscan2
- SAMSN1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1050323940; called by muse, mutect2, varscan2
- SBNO2 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777567099; called by muse, varscan2
- SCART1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62988082; called by muse, mutect2
- SCN7A | c.1983C>A p.D661E | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.389); catalogued as rs1366927319; called by muse, mutect2, varscan2
- SCRIB | c.4350del p.L1452Wfs*55 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs782243538, COSV57581753; called by mutect2, varscan2
- SEC16A | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs765552132; called by muse, mutect2
- SEMA4B | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs371202813; called by muse, mutect2, varscan2
- SEMA4C | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59691368; called by muse, mutect2
- SEPTIN3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187377656; called by muse, mutect2, varscan2
- SERINC3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs774380356, COSV54855641; called by muse, mutect2, varscan2
- SETDB1 | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1165832308; called by muse, mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs759211171; called by mutect2, varscan2
- SHLD2 | c.115del p.I39Ffs*12 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs750856045; called by mutect2, pindel, varscan2
- SIGLEC9 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs757055444, COSV51585638; called by muse, mutect2, varscan2
- SIK2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs746560391, COSV100232440; called by muse, mutect2, varscan2
- SKAP1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs757237792, COSV100412408; called by muse, mutect2, varscan2
- SLC16A8 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs965400443; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SLC34A1 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs765774780; called by muse, mutect2, varscan2
- SLC41A3 | c.150del p.K51Sfs*15 | Frame Shift Del (DEL) | VAF 19/189 reads (10%) | catalogued as COSV59989146; called by mutect2, pindel, varscan2
- SMARCA4 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100758449; called by muse, mutect2, varscan2
- SMOC2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144833047, COSV62438278; called by muse, mutect2, varscan2
- SOX1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1275116750; called by muse, mutect2, varscan2
- SOX11 | c.1148del p.G383Afs*39 | Frame Shift Del (DEL) | VAF 45/268 reads (17%) | catalogued as rs1553328038; called by mutect2, pindel, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 29/161 reads (18%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPINT1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs914334103; called by muse, mutect2, varscan2
- STAB2 | c.7453A>G p.I2485V | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs756813983; called by muse, mutect2, varscan2
- STAU2 | c.474del p.F158Lfs*16 (on ENST00000524300 / NM_001164380.2; = p.F126Lfs*16 on NM_014393.2) | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | catalogued as COSV63306705; called by mutect2, pindel, varscan2
- STKLD1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs587750666, COSV64312550; called by muse, mutect2
- STX5 | c.131del p.P44Qfs*2 | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | catalogued as rs746707646, COSV53677890; called by mutect2, varscan2
- TACC2 | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57749391; called by muse, mutect2, varscan2
- TAF6L | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145021229; called by muse, mutect2, varscan2
- TAL1 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs1354868044, COSV53746731; called by muse, mutect2
- TBC1D12 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56553165; called by muse, mutect2, varscan2
- TBC1D3F | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1203682699; called by muse, mutect2, varscan2
- TDP1 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs772139596, COSV100187945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD6 | c.2750dup p.N917Kfs*15 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | catalogued as rs765467808; called by mutect2, varscan2
- TERT | c.2074A>G p.T692A | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99721561; called by muse, mutect2, varscan2
- TERT | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57197208, COSV57203904; called by muse, mutect2, varscan2
- TFAP2C | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs774229244; called by muse, mutect2, varscan2
- THOC3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 40/619 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs747165298; called by muse, mutect2
- TIMM44 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759503572; called by muse, mutect2, varscan2
- TMEM120A | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.679); catalogued as rs377284594; called by muse, mutect2, varscan2
- TMPRSS5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs771255171; called by muse, mutect2, varscan2
- TNPO2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790347; called by muse, mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 51/222 reads (23%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS2 | c.1484del p.P495Rfs*25 (on ENST00000314250 / NM_170754.4; = p.P505Rfs*25 on NM_015319.2) | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs758743608; called by mutect2, pindel, varscan2
- TPD52L1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761264762, COSV59191844; called by muse, mutect2, varscan2
- TPST1 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758471610; called by muse, mutect2
- TRIM17 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757591425, COSV52858987; called by muse, mutect2, varscan2
- TRPM6 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 87/505 reads (17%) | catalogued as COSV62519388; called by muse, mutect2, varscan2
- TTBK2 | c.2627del p.N876Ifs*10 | Frame Shift Del (DEL) | VAF 45/353 reads (13%) | catalogued as rs1373884363; called by mutect2, pindel, varscan2
- UNC5CL | c.175del p.Q59Nfs*2 | Frame Shift Del (DEL) | VAF 40/216 reads (19%) | catalogued as rs748733935; called by mutect2, pindel, varscan2
- WDFY2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs974772381; called by muse, mutect2, varscan2
- WDR81 | c.365del p.G122Afs*132 | Frame Shift Del (DEL) | VAF 27/192 reads (14%) | catalogued as rs1204176409; called by mutect2, pindel, varscan2
- WIZ | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1434707651, COSV99652624; called by muse, mutect2
- XPR1 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1224126379; called by muse, mutect2, varscan2
- YLPM1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs778282189, COSV53115203; called by muse, mutect2, varscan2
- ZBTB46 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55509399; called by muse, mutect2, varscan2
- ZDHHC8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs771938147; called by muse, mutect2, varscan2
- ZNF516 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1454764847; called by muse, mutect2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | catalogued as rs1249713061; called by mutect2, pindel, varscan2
- ZNF608 | c.699dup p.H234Afs*34 | Frame Shift Ins (INS) | VAF 14/128 reads (11%) | catalogued as rs780943893; called by mutect2, pindel, varscan2
- ZXDC | c.1346C>A p.P449Q | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.647); catalogued as COSV60446187; called by muse, mutect2, varscan2
- A2ML1 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABHD16B | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ACAA1 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.316); called by muse, mutect2
- ACE | c.2596del p.A866Pfs*46 | Frame Shift Del (DEL) | VAF 35/242 reads (14%) | called by mutect2, pindel, varscan2
- ACHE | c.637T>C p.W213R | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSL4 | c.1821-3del | Splice Region (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- ADAM23 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM8 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS20 | c.5022A>G p.I1674M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2
- ADGRG6 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AGAP3 | c.1825C>T p.Q609* (on ENST00000622464; = p.Q645* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- AGRP | c.261_262dup p.V88Afs*2 | Frame Shift Ins (INS) | VAF 41/325 reads (13%) | called by mutect2, pindel, varscan2
- AK7 | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK2 | c.2307G>T p.R769S | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2
- ANAPC1 | c.1954A>T p.S652C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ANAPC15 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- ANKRD12 | c.5437_5438del p.L1813Gfs*11 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by pindel, varscan2
- ANKS1A | c.3244A>G p.I1082V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ANO2 | c.542T>C p.I181T (on ENST00000356134 / NM_001278597.3; = p.I185T on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- AP000471.1 | c.83del p.L28Cfs*14 | Frame Shift Del (DEL) | VAF 56/355 reads (16%) | called by mutect2, pindel, varscan2
- APOA1 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 32/535 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ARHGEF28 | c.2677del p.I893Ffs*5 | Frame Shift Del (DEL) | VAF 50/339 reads (15%) | called by mutect2, pindel, varscan2
- ARID1A | c.827del p.G276Efs*87 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, varscan2
- ARMC3 | c.160T>A p.L54I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ARSD | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATF4 | c.853del p.M285Wfs*36 | Frame Shift Del (DEL) | VAF 37/200 reads (19%) | called by mutect2, pindel, varscan2
- ATF6B | c.1937A>G p.E646G | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ATP10D | c.2033A>C p.Q678P | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATXN2L | c.2602C>T p.L868F | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- AVP | c.232_234del p.E78del | In Frame Del (DEL) | VAF 40/305 reads (13%) | called by pindel, varscan2
- B3GALT2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- BAHCC1 | c.3963dup p.S1322Qfs*8 | Frame Shift Ins (INS) | VAF 39/229 reads (17%) | called by mutect2, pindel, varscan2
- BARD1 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); called by muse, mutect2
- BCAR1 | c.2564A>G p.H855R | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BCL11B | c.887G>A p.G296D (on ENST00000357195 / NM_001282237.2; = p.G225D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- BCL2L11 | c.219del p.F73Lfs*11 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- BCL9L | c.308del p.P103Lfs*9 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- BOD1L1 | c.983G>T p.S328I | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- BPTF | c.3285del p.D1096Mfs*3 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6713C>T p.A2238V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BUD23 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- C12orf4 | c.40_41dup p.F15Nfs*8 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- C17orf49 | c.410A>T p.D137V | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- C1orf35 | c.735_736del p.H245Qfs*13 | Frame Shift Del (DEL) | VAF 50/380 reads (13%) | called by pindel, varscan2
- C21orf62 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C2CD2L | c.1395dup p.S466Lfs*19 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by pindel, varscan2
- C2orf72 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- C5AR2 | c.12T>A p.D4E | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C8B | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- CALCOCO2 | c.27del p.T10Hfs*72 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- CAMK2D | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- CCDC73 | c.2849T>C p.L950P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- CCDC73 | c.2021G>A p.C674Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by mutect2, varscan2
- CD74 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CD8B | c.44-2_47del p.X15_splice | Splice Site (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- CDC37L1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CDT1 | c.55del p.R19Afs*80 | Frame Shift Del (DEL) | VAF 62/350 reads (18%) | called by mutect2, varscan2
- CEND1 | c.330del p.P111Lfs*26 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- CEP162 | c.3542del p.N1181Mfs*3 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- CFAP54 | c.3944del p.L1315* | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- CFAP97 | c.1129T>C p.Y377H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CHST2 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHSY1 | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CIC | c.4586del p.P1529Lfs*91 | Frame Shift Del (DEL) | VAF 58/305 reads (19%) | called by mutect2, pindel, varscan2
- CLCN3 | c.1132del p.Y378Mfs*19 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- CLPX | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLUH | c.1715del p.P572Rfs*50 (on ENST00000435359; = p.P610Rfs*50 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/156 reads (15%) | called by mutect2, varscan2
- CLUL1 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2, varscan2
- CMTR2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A5 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CPAMD8 | c.757A>G p.I253V (on ENST00000651564; = p.I206V on NM_015692.5) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CTBP1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTSW | c.1020+2T>C p.X340_splice | Splice Site (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- CXXC4 | c.731dup p.I245Hfs*95 | Frame Shift Ins (INS) | VAF 15/158 reads (9%) | called by mutect2, pindel
- CXorf58 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CYP2C19 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DBNL | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- DCSTAMP | c.220del p.C74Afs*25 | Frame Shift Del (DEL) | VAF 80/499 reads (16%) | called by mutect2, pindel, varscan2
- DDN | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND4B | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHRS3 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX32 | c.2015T>C p.I672T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- DIDO1 | c.3497C>T p.A1166V | Missense Mutation (SNP) | VAF 22/519 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2
- DIP2A | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2
- DNAH1 | c.12424A>G p.I4142V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DNAH6 | c.3448A>G p.N1150D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DNAJA3 | c.1133del p.P378Lfs*39 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | called by pindel, varscan2
- DNMBP | c.2801T>C p.M934T | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- DPPA4 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DYNC2H1 | c.3610C>T p.H1204Y | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.625); called by muse, mutect2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/270 reads (11%) | called by mutect2, varscan2
- ECM1 | c.1037A>C p.Q346P | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, varscan2
- EIF4ENIF1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMD | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- EPB41L3 | c.2576A>G p.E859G | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- EPB41L3 | c.1465del p.E489Kfs*78 | Frame Shift Del (DEL) | VAF 44/264 reads (17%) | called by mutect2, varscan2
- EPHA6 | c.2483dup p.G829Rfs*33 (on ENST00000389672 / NM_001080448.3; = p.G221Rfs*33 on NM_173655.4) | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | called by mutect2, pindel
- ESPN | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 129/630 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- EVC2 | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 19/487 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- F2RL1 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 40/200 reads (20%) | called by mutect2, varscan2
- FAM171A1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM193A | c.2217C>T p.C739= | Splice Region (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- FBF1 | c.1932G>T p.E644D (on ENST00000586717; = p.E658D on NM_001319193.1) | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXW8 | c.911T>C p.V304A (on ENST00000309909; = p.V342A on NM_012174.1) | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FCGBP | c.2477G>A p.C826Y | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FILIP1 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FLAD1 | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.434); called by muse, mutect2
- FLG | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 82/667 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- FN1 | c.5335G>A p.V1779I | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FOXP2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- FRMD4B | c.3012T>A p.D1004E | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FUCA1 | c.1197del p.L400Cfs*9 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- FZR1 | c.995del p.G332Afs*14 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- GBP4 | c.1197_1197+2del p.X399_splice | Splice Site (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- GIPC1 | c.344del p.G115Afs*13 | Frame Shift Del (DEL) | VAF 29/167 reads (17%) | called by mutect2, varscan2
- GLB1L3 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GLIS2 | c.421del p.A141Pfs*110 | Frame Shift Del (DEL) | VAF 46/246 reads (19%) | called by mutect2, varscan2
- GLRB | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- GNG14 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- GOLT1B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GPATCH8 | c.1946del p.G649Vfs*460 | Frame Shift Del (DEL) | VAF 36/272 reads (13%) | called by mutect2, pindel, varscan2
- GPN2 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR143 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPRC5B | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- GPRC5B | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GREB1L | c.4351T>G p.F1451V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIN2B | c.3754T>C p.Y1252H | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GSDMD | c.1275del p.L427Sfs*21 | Frame Shift Del (DEL) | VAF 43/254 reads (17%) | called by mutect2, pindel, varscan2
- GSG1L2 | c.373T>C p.S125P | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- GUCY2F | c.2915T>A p.M972K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HERC1 | c.5446A>G p.T1816A | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HERC2 | c.10934A>G p.Q3645R | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HIPK2 | c.1487A>C p.D496A | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HROB | c.409del p.L137Yfs*66 | Frame Shift Del (DEL) | VAF 32/259 reads (12%) | called by mutect2, pindel, varscan2
- HS6ST1 | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 89/724 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, varscan2
- HSP90AB1 | c.638T>G p.I213S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90B1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- HSPB6 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPG2 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 109/638 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.13757A>G p.E4586G | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- HYDIN | c.7282A>C p.S2428R | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- HYOU1 | c.815del p.G272Afs*62 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by mutect2, pindel
- IGHD | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 88/565 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- INTS4 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- IQSEC1 | c.2242_2243del p.L748Afs*13 | Frame Shift Del (DEL) | VAF 28/175 reads (16%) | called by pindel, varscan2
- IQSEC3 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ITIH5 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- ITPRID1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- JMJD4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- JPH1 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 92/554 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH3 | c.478del p.L160* | Frame Shift Del (DEL) | VAF 52/352 reads (15%) | called by mutect2, pindel, varscan2
- KDM4B | c.2459G>A p.C820Y | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0100 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2
- KIAA0586 | c.1938del p.G647Dfs*20 (on ENST00000619416 / NM_001244190.2; = p.G586Dfs*20 on NM_014749.5) | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.131del p.P44Qfs*34 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | called by mutect2, pindel, varscan2
- KIF17 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIF21A | c.2399del p.K800Rfs*38 (on ENST00000361418 / NM_001378440.1; = p.K787Rfs*38 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- KIF26B | c.5570_5571insT p.R1858Afs*131 | Frame Shift Ins (INS) | VAF 71/522 reads (14%) | called by mutect2, pindel, varscan2
- KIF4B | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 40/214 reads (19%) | called by muse, mutect2, varscan2
- KIF5B | c.1864del p.M622Wfs*8 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, varscan2
- KIFC3 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- KIN | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLB | c.1752dup p.Q585Tfs*3 | Frame Shift Ins (INS) | VAF 34/302 reads (11%) | called by mutect2, pindel, varscan2
- KMT2D | c.7471del p.A2491Lfs*52 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel
- KPNA3 | c.1310del p.N437Tfs*3 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- KRT19 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- KRTAP12-3 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 73/480 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LAMA5 | c.5966G>A p.G1989D | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDB1 | c.404dup p.A136Cfs*9 (on ENST00000425280 / NM_001321612.2; = p.A100Cfs*9 on NM_003893.5) | Frame Shift Ins (INS) | VAF 32/218 reads (15%) | called by mutect2, pindel, varscan2
- LGALS1 | c.202del p.A68Pfs*30 | Frame Shift Del (DEL) | VAF 31/190 reads (16%) | called by mutect2, pindel, varscan2
- LIPH | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LSM1 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LTC4S | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 60/379 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MAGI3 | c.1246del p.S416Afs*21 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | called by mutect2, pindel, varscan2
- MAP1S | c.593del p.P198Rfs*93 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- MAP3K4 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MCF2L2 | c.3063_3064del p.C1021* | Nonsense Mutation (DEL) | VAF 16/183 reads (9%) | called by pindel, varscan2
- MCRIP2 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MCTS1 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- MDN1 | c.10345T>G p.F3449V | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2
- MED13 | c.2488C>T p.L830F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEIS2 | c.650_652del p.S217del (on ENST00000561208 / NM_170675.5; = p.S204del on NM_002399.3) | In Frame Del (DEL) | VAF 28/161 reads (17%) | called by pindel, varscan2
- MEX3A | c.1334del p.P445Rfs*33 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- MEX3A | c.943A>G p.S315G | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MGAT4B | c.85A>G p.S29G | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- MICAL1 | c.1349del p.N450Tfs*20 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, varscan2
- MOK | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MPND | c.896del p.G299Afs*10 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by pindel, varscan2
- MROH1 | c.3367G>T p.A1123S | Missense Mutation (SNP) | VAF 32/1108 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- MSANTD3 | c.584del p.K195Rfs*18 | Frame Shift Del (DEL) | VAF 23/153 reads (15%) | called by mutect2, pindel, varscan2
- MUC2 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MUC5B | c.11752G>T p.V3918L | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by mutect2, varscan2
- MUC5B | c.15134C>T p.A5045V | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.281); called by muse, mutect2
- MYH1 | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MYH7 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 81/484 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MYO15B | c.3580dup p.R1194Pfs*96 | Frame Shift Ins (INS) | VAF 19/151 reads (13%) | called by mutect2, pindel, varscan2
- MYO16 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- MYO5B | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 101/569 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NAA60 | c.8_9dup p.V4Rfs*21 | Frame Shift Ins (INS) | VAF 14/116 reads (12%) | called by mutect2, varscan2
- NAMPT | c.687dup p.Y230Ifs*29 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- NANOS1 | c.53del p.P18Rfs*12 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- NAV1 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- NEB | c.7133A>G p.D2378G | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NECTIN2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NEURL4 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 91/504 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- NHLRC2 | c.1456del p.R486Gfs*27 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- NLK | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP11 | c.503T>C p.L168S | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NME1 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 102/619 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOL4L | c.495_497del p.D166del | In Frame Del (DEL) | VAF 46/336 reads (14%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 99/485 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- NRBP2 | c.1382-5C>T | Splice Region (SNP) | VAF 46/291 reads (16%) | called by muse, mutect2, varscan2
- NRCAM | c.3536T>A p.L1179H (on ENST00000379028 / NM_001371124.1; = p.L1058H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRDE2 | c.2595G>T p.Q865H | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NRXN2 | c.3733C>A p.P1245T | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- NUP62CL | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2
- OBSCN | c.16561G>A p.A5521T | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- OR10G8 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- OR4B1 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR51A7 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- OR52E4 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PACSIN3 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PBRM1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB4 | c.338T>A p.V113E | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PCDHB4 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCDHGA9 | c.1361A>G p.Q454R | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); called by muse, mutect2
- PCDHGB6 | c.1334T>A p.I445N | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PCSK5 | c.4802A>G p.H1601R | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER3 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, varscan2
- PGA3 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.408); called by mutect2, varscan2
- PGBD1 | c.1380_1381del p.F461Wfs*13 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | called by pindel, varscan2
- PHTF2 | c.416del p.F139Sfs*14 (on ENST00000248550 / NM_001366089.1; = p.F101Sfs*14 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by pindel, varscan2
- PHYKPL | c.582del p.K194Nfs*62 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- PICALM | c.1787del p.P596Lfs*2 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- POLG | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2
- POM121 | c.2267C>A p.S756Y (on ENST00000434423; = p.S491Y on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/764 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PPEF1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PPP1R13B | c.2846C>T p.A949V | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM16 | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PRDM7 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PRMT2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PROB1 | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PROM1 | c.2583-3dup | Splice Region (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel
- PROM2 | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PROSER2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- PRRC2A | c.2657dup p.K887* | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- PRRC2B | c.6328del p.R2110Efs*13 | Frame Shift Del (DEL) | VAF 42/291 reads (14%) | called by mutect2, pindel, varscan2
- PTEN | c.751_755dup p.D252Efs*6 | Frame Shift Ins (INS) | VAF 41/164 reads (25%) | called by mutect2, pindel, varscan2
- PTPN11 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PTPRN2 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PTPRZ1 | c.5929C>T p.Q1977* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- PZP | c.2407A>C p.T803P | Missense Mutation (SNP) | VAF 66/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- QSER1 | c.3895A>G p.T1299A (on ENST00000399302; = p.T1428A on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.3015del p.F1005Lfs*52 | Frame Shift Del (DEL) | VAF 24/204 reads (12%) | called by mutect2, pindel, varscan2
- RAB40AL | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RABGAP1 | c.1034G>T p.R345M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RBAK | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by muse, mutect2
- RBP2 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REEP4 | c.32+1G>A p.X11_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- RIC1 | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- RIOX1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); called by muse, varscan2
- RSRP1 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RTN4RL1 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.2791T>C p.Y931H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2
- SALL1 | c.3339_3340del p.S1114Ffs*60 | Frame Shift Del (DEL) | VAF 50/251 reads (20%) | called by mutect2, pindel, varscan2
- SALL3 | c.421del p.D141Tfs*26 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel, varscan2
- SAMD15 | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2
- SBF2 | c.1395+2T>C p.X465_splice | Splice Site (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- SBNO2 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SCARA3 | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2
- SCN5A | c.1711A>G p.S571G | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2
- SCRN2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.086); called by muse, mutect2
- SDCBP | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SEMA3E | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SERPINC1 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SETBP1 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- SETD2 | c.2749del p.S917Vfs*5 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- SH2D3A | c.899A>G p.Q300R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3TC1 | c.1381dup p.Q461Pfs*124 | Frame Shift Ins (INS) | VAF 22/139 reads (16%) | called by mutect2, pindel, varscan2
- SHANK3 | c.3742del p.R1248Gfs*29 | Frame Shift Del (DEL) | VAF 41/282 reads (15%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- SHC2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIK2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIRPB1 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.257); called by muse, mutect2
- SLC17A9 | c.578T>G p.L193R | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC20A1 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- SLC22A18AS | c.658del p.R220Afs*13 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- SLC25A34 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC27A5 | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A1 | c.1562dup p.A522Gfs*138 | Frame Shift Ins (INS) | VAF 34/164 reads (21%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.2674T>C p.*892Rext*23 | Nonstop Mutation (SNP) | VAF 51/368 reads (14%) | called by muse, mutect2, varscan2
- SLC5A5 | c.1279del p.L427Cfs*23 | Frame Shift Del (DEL) | VAF 92/597 reads (15%) | called by mutect2, pindel, varscan2
- SMTNL2 | c.308del p.P103Rfs*43 | Frame Shift Del (DEL) | VAF 22/173 reads (13%) | called by mutect2, pindel, varscan2
- SNRPB | c.20_22del p.S7del | In Frame Del (DEL) | VAF 24/134 reads (18%) | called by pindel, varscan2
- SNRPF | c.353T>C p.L118S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SORL1 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- SPEG | c.6618del p.A2207Hfs*32 | Frame Shift Del (DEL) | VAF 39/251 reads (16%) | called by mutect2, pindel, varscan2
- SPIDR | c.394A>G p.S132G | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SRCAP | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SRGAP1 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- STAMBPL1 | c.539dup p.E181Rfs*27 | Frame Shift Ins (INS) | VAF 14/152 reads (9%) | called by mutect2, pindel
- STIP1 | c.768dup p.T257Hfs*2 | Frame Shift Ins (INS) | VAF 40/302 reads (13%) | called by mutect2, pindel, varscan2
- STMND1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SYCP2 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SYNE1 | c.13813T>A p.Y4605N (on ENST00000367255 / NM_182961.4; = p.Y4534N on NM_033071.3) | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SYNJ2 | c.4318G>T p.G1440* | Nonsense Mutation (SNP) | VAF 46/233 reads (20%) | called by muse, mutect2, varscan2
- TAF3 | c.1580del p.K527Rfs*3 | Frame Shift Del (DEL) | VAF 19/178 reads (11%) | called by mutect2, pindel, varscan2
- TAF5 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAF6 | c.1779del p.S594Afs*111 | Frame Shift Del (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- TAS2R4 | c.252del p.F84Lfs*16 | Frame Shift Del (DEL) | VAF 29/142 reads (20%) | called by mutect2, pindel, varscan2
- TBC1D4 | c.2875C>T p.L959F | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCERG1 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TCHH | c.437G>T p.R146M | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TDO2 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- TDRD9 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TERT | c.2305C>T p.L769F | Missense Mutation (SNP) | VAF 102/748 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TEX11 | c.370-2A>G p.X124_splice (on ENST00000344304; = p.X109_splice on NM_031276.3) | Splice Site (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- THSD1 | c.766del p.V256* | Frame Shift Del (DEL) | VAF 32/256 reads (13%) | called by mutect2, pindel, varscan2
- TJP2 | c.2777A>G p.D926G | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TLE1 | c.1389del p.D464Tfs*27 | Frame Shift Del (DEL) | VAF 40/209 reads (19%) | called by mutect2, varscan2
- TMEM132A | c.2671del p.Q891Sfs*15 (on ENST00000453848 / NM_178031.3; = p.Q892Sfs*15 on NM_017870.4) | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by mutect2, pindel, varscan2
- TMPRSS2 | c.997del p.S333Lfs*16 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- TNNC2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNR | c.637dup p.V213Gfs*10 | Frame Shift Ins (INS) | VAF 29/273 reads (11%) | called by mutect2, pindel
- TNRC6B | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TP53BP2 | c.443T>A p.I148N (on ENST00000343537 / NM_001031685.3; = p.I19N on NM_005426.2) | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- TPBGL | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TPR | c.5093G>A p.R1698H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TRAPPC12 | c.821del p.P274Rfs*25 | Frame Shift Del (DEL) | VAF 47/291 reads (16%) | called by mutect2, pindel, varscan2
- TRAV10 | c.57del p.X19_splice | Splice Site (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- TRIM2 | c.364G>T p.D122Y (on ENST00000437508; = p.D149Y on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TRIM3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM51GP | c.1132T>G p.F378V | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRMO | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- TRPC7 | c.2183G>A p.C728Y | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TSPAN9 | c.260dup p.I88Hfs*57 | Frame Shift Ins (INS) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTC3 | c.4665A>T p.E1555D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TUBGCP2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- TUBGCP5 | c.2603A>G p.Q868R | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXLNB | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2U | c.302C>A p.T101K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- UBE3B | c.2423A>G p.H808R | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- UBR4 | c.3697T>C p.W1233R | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UNC13B | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- UNC5D | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- URB1 | c.561T>A p.D187E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- USH2A | c.9819C>G p.Y3273* | Nonsense Mutation (SNP) | VAF 66/438 reads (15%) | called by muse, mutect2, varscan2
- USP20 | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP34 | c.7379del p.L2460Cfs*58 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- USP44 | c.1189_1190del p.W397Gfs*33 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- VAT1L | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- VPS13A | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- VPS50 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/182 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- VXN | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- WDR87 | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WIPI1 | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- WNT6 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB1 | c.586dup p.S196Kfs*24 | Frame Shift Ins (INS) | VAF 20/125 reads (16%) | called by mutect2, varscan2
- ZBTB32 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZBTB47 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2
- ZBTB47 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZCCHC12 | c.178A>C p.T60P | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFAND2A | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, varscan2
- ZFAND2A | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZFHX3 | c.10062del p.L3355Cfs*130 | Frame Shift Del (DEL) | VAF 27/130 reads (21%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZNF142 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ZNF250 | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF324 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF48 | c.733_739delinsAGCAG p.E245Sfs*34 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by pindel, varscan2*
- ZNF583 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF699 | c.1852A>G p.K618E | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2
- ZNF786 | c.2028del p.Q677Sfs*11 | Frame Shift Del (DEL) | VAF 24/223 reads (11%) | called by mutect2, pindel, varscan2
- ZNF793 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by mutect2, varscan2
- ZNF835 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF843 | c.529A>C p.S177R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.685); called by muse, mutect2
- ZSCAN10 | c.1546G>A p.V516M (on ENST00000252463; = p.V571M on NM_032805.3) | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ZXDA | c.120dup p.T41Hfs*42 | Frame Shift Ins (INS) | VAF 23/194 reads (12%) | called by mutect2, pindel, varscan2
- AAMP | c.108T>C p.G36= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- ABHD16B | c.1107C>G p.T369= | Silent (SNP) | VAF 18/195 reads (9%) | called by muse, mutect2
- ADGRB1 | c.2982C>T p.S994= | Silent (SNP) | VAF 49/240 reads (20%) | called by muse, mutect2
- ADGRB3 | c.3282C>T p.N1094= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as rs138734026; called by muse, mutect2
- AGRN | c.2367C>T p.C789= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as rs765771215; called by muse, mutect2, varscan2
- AHNAK | c.3480C>T p.P1160= | Silent (SNP) | VAF 32/264 reads (12%) | catalogued as rs201692519; called by muse, mutect2, varscan2
- ALDH1A3 | c.333C>T p.R111= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs560418569, COSV100320251; called by muse, mutect2, varscan2
- ANO1 | c.534G>A p.T178= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs369100980; called by muse, mutect2, varscan2
- AP5B1 | c.291G>A p.L97= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs1206805364, COSV57504759; called by muse, mutect2, varscan2
- APBB1IP | c.1755G>A p.P585= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs1453807350; called by muse, mutect2
- ARFRP1 | c.363C>T p.S121= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as rs770198881; called by muse, mutect2, varscan2
- ARHGAP44 | c.897G>T p.L299= | Silent (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- ATP2A2 | c.2103C>T p.G701= | Silent (SNP) | VAF 52/376 reads (14%) | catalogued as rs765382896, COSV57875721; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATXN3 | c.516C>T p.C172= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs748191546, COSV61495108; called by muse, varscan2
- BHMG1 | c.366C>T p.A122= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs1235661941; called by muse, mutect2
- BICDL2 | c.939C>T p.D313= | Silent (SNP) | VAF 61/300 reads (20%) | called by muse, mutect2, varscan2
- BRICD5 | c.106C>T p.L36= | Silent (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2
- CA11 | c.231G>A p.R77= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs778947350; called by muse, mutect2, varscan2
- CCDC106 | c.39C>T p.D13= | Silent (SNP) | VAF 52/286 reads (18%) | called by muse, mutect2, varscan2
- CCDC168 | c.19989T>C p.G6663= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- CCM2 | c.960A>G p.A320= | Silent (SNP) | VAF 92/458 reads (20%) | catalogued as rs1174545935; called by muse, varscan2
- CD4 | c.174G>A p.Q58= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- CD93 | c.1161T>C p.D387= | Silent (SNP) | VAF 13/205 reads (6%) | called by muse, mutect2
- CDC73 | c.198C>T p.N66= | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as rs1216098981; ClinVar: likely benign; called by muse, varscan2
- CELSR3 | c.2239C>T p.L747= | Silent (SNP) | VAF 40/233 reads (17%) | called by muse, mutect2, varscan2
- CENPF | c.4680G>A p.R1560= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- CHAF1B | c.1290C>T p.P430= | Silent (SNP) | VAF 36/207 reads (17%) | catalogued as rs749146474, COSV100023469; called by muse, mutect2, varscan2
- CHD9 | c.6087C>A p.T2029= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- CILP | c.186C>T p.I62= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as rs1447434677, COSV99973936; called by muse, mutect2, varscan2
- CLPTM1L | c.1596G>A p.T532= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as rs368308827; called by muse, mutect2, varscan2
- CLU | c.1029G>A p.E343= | Silent (SNP) | VAF 62/447 reads (14%) | catalogued as CM1512514; called by muse, mutect2, varscan2
- CMTM4 | c.93C>T p.T31= | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as rs965682702; called by muse, mutect2, varscan2
- CNNM1 | c.459C>T p.G153= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CNTRL | c.4761C>T p.S1587= | Silent (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2
- COG8 | c.1302C>A p.P434= | Silent (SNP) | VAF 33/535 reads (6%) | called by muse, mutect2
- COL8A1 | c.639A>G p.P213= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- CORO7 | c.852G>A p.Q284= | Silent (SNP) | VAF 43/278 reads (15%) | called by muse, mutect2, varscan2
- CREBBP | c.6258G>A p.V2086= | Silent (SNP) | VAF 131/815 reads (16%) | called by muse, mutect2, varscan2
- CROCC2 | c.2790G>A p.R930= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV69132283; called by muse, mutect2, varscan2
- CRYL1 | c.24C>T p.C8= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1406563071; called by muse, mutect2, varscan2
- CTSD | c.1128G>A p.P376= | Silent (SNP) | VAF 13/404 reads (3%) | catalogued as rs929763593, COSV52589592; ClinVar: likely benign; called by muse, mutect2
- CYP26C1 | c.285C>T p.R95= | Silent (SNP) | VAF 23/375 reads (6%) | called by muse, mutect2
- CYP4F2 | c.555T>C p.G185= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as COSV50000447; called by muse, mutect2, varscan2
- DAPK1 | c.2340G>A p.P780= | Silent (SNP) | VAF 31/310 reads (10%) | catalogued as rs545837227, COSV63786689; called by muse, mutect2, varscan2
- DDX3X | c.1815C>T p.S605= (on ENST00000399959; = p.S606= on NM_001356.5) | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as rs1291725741; called by muse, mutect2, varscan2
- DEAF1 | c.780C>T p.G260= | Silent (SNP) | VAF 16/478 reads (3%) | called by muse, mutect2
- DIP2A | c.1905C>T p.A635= | Silent (SNP) | VAF 50/204 reads (25%) | catalogued as rs372346078; called by muse, mutect2, varscan2
329 further variants in this file (0 protein-altering or splice-affecting, 188 silent, 141 other) are not listed here.
